Somatic mutation profile of tumor specimen TCGA-04-1651-01A (aliquot TCGA-04-1651-01A-01W-0639-09) from TCGA case TCGA-04-1651, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.7 years (19,628 days).
Specimen TCGA-04-1651-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29aaa420-04e9-484c-8d4f-c92ee0bed8a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1651-11A (Solid Tissue Normal), aliquot TCGA-04-1651-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7bc1cb2-6fc2-475a-9a48-8f93d6332062

The open-access MAF lists 85 somatic variants for this specimen: 58 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 23, Nonsense Mutation 9, Frame Shift Ins 3, Splice Site 3, RNA 2, Intron 2, Frame Shift Del 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC006059.2 | c.1864G>T p.E622* | Nonsense Mutation (SNP) | VAF 14/202 reads (7%) | catalogued as COSV100044972; called by muse, mutect2
- ADGRE5 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as rs376892799; called by muse, mutect2, varscan2
- AFAP1L1 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs755876664, COSV57044011; called by muse, mutect2, varscan2
- ALG10B | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 224/553 reads (41%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.447); catalogued as COSV58144728; called by muse, mutect2, varscan2
- BTBD7 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.279); catalogued as COSV100107828; called by muse, mutect2
- C20orf194 | c.725T>G p.F242C | Missense Mutation (SNP) | VAF 320/505 reads (63%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as rs1287752437, COSV52701818; called by muse, mutect2, varscan2
- CCR3 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 111/288 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62465625; called by muse, mutect2, varscan2
- CHD6 | c.5581C>T p.Q1861* | Nonsense Mutation (SNP) | VAF 57/408 reads (14%) | catalogued as COSV64693922; called by muse, mutect2, varscan2
- COL2A1 | c.3505G>A p.V1169I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as rs760390497, COSV61533325; called by muse, mutect2, varscan2
- EPB42 | c.834G>T p.V278= (on ENST00000441366 / NM_001114134.2; = p.V308= on NM_000119.3) | Splice Region (SNP) | VAF 29/56 reads (52%) | catalogued as COSV55751371; called by muse, varscan2
- EWSR1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 159/621 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV58426983; called by muse, mutect2, varscan2
- F8 | c.4779G>T p.Q1593H | Missense Mutation (SNP) | VAF 42/1000 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV64280650; called by muse, mutect2
- GDF3 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 114/296 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as rs1049872479, COSV61713489; called by muse, mutect2, varscan2
- GPR158 | c.2782C>T p.R928C | Missense Mutation (SNP) | VAF 212/503 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs149419744; called by muse, mutect2, varscan2
- H4C12 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.228); catalogued as COSV62744003; called by muse, varscan2
- HMGCR | c.231C>A p.Y77* | Nonsense Mutation (SNP) | VAF 9/138 reads (7%) | catalogued as COSV99842895; called by muse, mutect2
- IFT20 | c.295G>A p.E99K (on ENST00000395418 / NM_001267776.2; = p.R138K on NM_174887.4) | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99880546; called by muse, mutect2
- IKZF5 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 16/447 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100924722; called by muse, mutect2
- IL12RB2 | c.2539A>T p.K847* | Nonsense Mutation (SNP) | VAF 50/1096 reads (5%) | catalogued as COSV99254475; called by muse, mutect2
- KCNG1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV65370361; called by muse, mutect2
- KDM6A | c.3797C>G p.S1266* | Nonsense Mutation (SNP) | VAF 12/366 reads (3%) | catalogued as COSV100937725; called by muse, mutect2
- KRT9 | c.1170G>C p.K390N | Missense Mutation (SNP) | VAF 163/180 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV55855131; called by muse, mutect2, varscan2
- LAMA1 | c.1140T>A p.Y380* | Nonsense Mutation (SNP) | VAF 28/776 reads (4%) | catalogued as COSV101054371; called by muse, mutect2
- LRRIQ4 | c.1304A>T p.Q435L | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV61620069; called by muse, mutect2, varscan2
- LRRN2 | c.1279C>G p.R427G | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV65784569; called by muse, mutect2, varscan2
- LY75 | c.3469C>A p.H1157N | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV55108571; called by muse, mutect2
- MASTL | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 130/261 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV60912391; called by muse, mutect2, varscan2
- MCM8 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 17/657 reads (3%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.962); catalogued as COSV54521440, COSV99494880; called by muse, mutect2
- MSX2 | c.496T>A p.Y166N | Missense Mutation (SNP) | VAF 106/149 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53327278, COSV53328184; called by muse, mutect2, varscan2
- MTMR8 | c.2070C>G p.I690M | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as rs772021955, COSV100878161; called by muse, mutect2
- MYOM2 | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV50763162; called by muse, mutect2, varscan2
- NEB | c.7803C>A p.S2601R | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs1157483366, COSV99413190; called by muse, mutect2
- PDZD2 | c.477-1G>T p.X159_splice | Splice Site (SNP) | VAF 102/174 reads (59%) | catalogued as COSV56870828; called by muse, mutect2, varscan2
- PITX2 | c.920G>C p.S307T (on ENST00000354925 / NM_001204397.1; = p.S314T on NM_000325.6) | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as COSV60740040, COSV60742137; called by muse, mutect2, varscan2
- PPFIA1 | c.2000G>C p.G667A | Missense Mutation (SNP) | VAF 192/488 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV54140106, COSV54141191; called by muse, mutect2, varscan2
- SAT1 | c.462G>C p.W154C | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100803819; called by muse, mutect2
- SERPINC1 | c.1298C>G p.T433S | Missense Mutation (SNP) | VAF 103/372 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV62930440; called by muse, mutect2, varscan2
- SLC24A5 | c.250T>A p.S84T | Missense Mutation (SNP) | VAF 191/399 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV58319182; called by muse, mutect2, varscan2
- SON | c.22A>C p.I8L | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); catalogued as COSV51669263; called by muse, mutect2, varscan2
- SORCS1 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 127/288 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV53900308; called by muse, mutect2, varscan2
- SPATA31E1 | c.3505G>C p.A1169P | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV57794765; called by muse, mutect2, varscan2
- SPX | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 83/390 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.224); catalogued as COSV57021681; called by muse, mutect2, varscan2
- SREBF1 | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs920839534, COSV55419555; called by muse, mutect2, varscan2
- SYT3 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV58898781; called by muse, mutect2, varscan2
- TMEM62 | c.545C>A p.S182* | Nonsense Mutation (SNP) | VAF 221/470 reads (47%) | catalogued as COSV53040771, COSV53042690; called by muse, mutect2, varscan2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 57/68 reads (84%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- UGT2B4 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs752000647, COSV59320021, COSV59321143; called by muse, mutect2, varscan2
- USP28 | c.2663G>A p.W888* | Nonsense Mutation (SNP) | VAF 37/109 reads (34%) | catalogued as COSV50184927; called by muse, mutect2, varscan2
- VPS13B | c.3037G>T p.A1013S | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.53); catalogued as COSV62144867; called by muse, mutect2, varscan2
- XXYLT1 | c.846dup p.E283Rfs*85 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | catalogued as rs745401645; called by pindel, varscan2
- ZNF345 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 169/390 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV59324517; called by muse, mutect2, varscan2
- CAPG | c.68dup p.W24Vfs*50 | Frame Shift Ins (INS) | VAF 28/66 reads (42%) | called by mutect2, pindel
- CCL15 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CIR1 | c.252+1_252+37del p.X84_splice | Splice Site (DEL) | VAF 35/66 reads (53%) | called by mutect2, pindel
- FAM81B | c.308del p.L103Pfs*12 | Frame Shift Del (DEL) | VAF 112/170 reads (66%) | called by mutect2, pindel, varscan2
- KDM5C | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, mutect2
- VN1R2 | c.681dup p.P228Sfs*27 | Frame Shift Ins (INS) | VAF 57/173 reads (33%) | called by mutect2, pindel, varscan2
- ZNF236 | c.969_978+38del p.X323_splice | Splice Site (DEL) | VAF 12/132 reads (9%) | called by mutect2, pindel
- ADCY9 | c.1206C>G p.G402= | Silent (SNP) | VAF 73/116 reads (63%) | catalogued as COSV53580951; called by muse, mutect2, varscan2
- ARSB | c.1504C>T p.L502= | Silent (SNP) | VAF 73/77 reads (95%) | catalogued as COSV53728451; called by muse, mutect2, varscan2
- BSN | c.10176A>T p.A3392= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV56526147; called by muse, mutect2, varscan2
- CD1C | c.984A>C p.S328= | Silent (SNP) | VAF 365/1218 reads (30%) | catalogued as COSV63807416; called by muse, mutect2, varscan2
- DUOX2 | c.3447C>T p.V1149= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV101199504; called by muse, mutect2
- DUSP29 | c.501C>T p.D167= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV58301490; called by muse, mutect2, varscan2
- FMN1 | c.3783C>G p.V1261= (on ENST00000616417 / NM_001277313.2; = p.V1038= on NM_001103184.4) | Silent (SNP) | VAF 10/215 reads (5%) | catalogued as COSV100567687; called by muse, mutect2
- GRM7 | c.2230A>C p.R744= | Silent (SNP) | VAF 102/179 reads (57%) | catalogued as COSV63166716; called by muse, mutect2, varscan2
- HEATR1 | c.5778A>G p.E1926= | Silent (SNP) | VAF 218/515 reads (42%) | catalogued as COSV63982834; called by muse, mutect2, varscan2
- LRRC4C | c.1341C>T p.T447= | Silent (SNP) | VAF 29/305 reads (10%) | catalogued as COSV99536393; called by muse, mutect2, varscan2
- LRRC4C | c.1002C>T p.P334= | Silent (SNP) | VAF 15/205 reads (7%) | catalogued as COSV99536395; called by muse, mutect2
- LY6G6F-LY6G6D | c.168C>A p.G56= | Silent (SNP) | VAF 24/26 reads (92%) | catalogued as COSV65443173; called by muse, mutect2, varscan2
- PINK1 | c.934C>A p.R312= | Silent (SNP) | VAF 47/54 reads (87%) | catalogued as COSV100387352, COSV58632757; called by muse, mutect2, varscan2
- PKD2L2 | c.174C>T p.N58= | Silent (SNP) | VAF 11/210 reads (5%) | catalogued as COSV99295832; called by muse, mutect2
- PLEK | c.249A>T p.A83= | Silent (SNP) | VAF 281/580 reads (48%) | catalogued as COSV52250852, COSV52253682; called by muse, mutect2, varscan2
- RAPGEF5 | c.1623G>A p.Q541= (on ENST00000401957 / NM_001367602.2; = p.Q844= on NM_012294.5) | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs777019272, COSV59790751; called by muse, mutect2, varscan2
- RUNX2 | c.993C>T p.A331= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as COSV100766974; called by muse, mutect2
- SEC31A | c.3459G>C p.L1153= (on ENST00000355196 / NM_001318120.1; = p.L1114= on NM_016211.4) | Silent (SNP) | VAF 110/127 reads (87%) | catalogued as COSV52350912; called by muse, mutect2, varscan2
- TENT4B | c.1626C>A p.T542= (on ENST00000561678 / NM_001365323.2; = p.T527= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/232 reads (3%) | called by muse, mutect2
- TRPM8 | c.1632C>T p.D544= | Silent (SNP) | VAF 72/117 reads (62%) | catalogued as rs142882642; called by muse, mutect2, varscan2
- UIMC1 | c.1539A>T p.P513= | Silent (SNP) | VAF 30/604 reads (5%) | catalogued as COSV101021960; called by muse, mutect2
- UNC5C | c.396A>G p.E132= | Silent (SNP) | VAF 69/85 reads (81%) | catalogued as COSV71661946; called by muse, mutect2, varscan2
- ZNF700 | c.1632C>G p.A544= | Silent (SNP) | VAF 43/232 reads (19%) | catalogued as COSV54315036; called by muse, mutect2, varscan2
- DLG2 | c.205-65699C>T | Intron (SNP) | VAF 18/294 reads (6%) | catalogued as rs1322212106, COSV99711701, COSV99713913; called by muse, mutect2
- NBPF7 | n.919G>A | RNA (SNP) | VAF 146/284 reads (51%) | called by muse, varscan2
- NBPF7 | n.918A>G | RNA (SNP) | VAF 151/281 reads (54%) | called by muse, mutect2, varscan2
- RPGR | c.2520+1313G>C | Intron (SNP) | VAF 65/183 reads (36%) | catalogued as COSV58839507; called by muse, mutect2, varscan2
